Gene-level copy-number profile of tumor specimen TARGET-10-PASHUP-09A from TARGET case TARGET-10-PASHUP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,534 days).
Specimen TARGET-10-PASHUP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.b5a2defd-815d-5d26-8ba9-a2d9a262e621.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASHUP-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/f9d1b709-87d9-46c2-ab05-b01196ac28d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 181; copy number 1: 2,834; copy number 2: 56,843; copy number 3: 219; copy number 4: 184.

Homozygous deletions (total copy number 0; autosomes only): 181 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:38,273,587–38,311,808, 6 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,636,924–142,786,224, 19 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–1): FOCAD.
- chr9:20,716,105–23,898,054, 71 genes (broad region; genes not listed).
- chr12:23,108,458–23,108,493, 1 gene: AC087258.1.
- chr14:22,011,910–22,518,871, 78 genes (broad region; genes not listed).
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 445. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
